Somatic mutation profile of tumor specimen 0DL6SE from CCDI case PBBXTR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.4 years (5,251 days).
Specimen 0DL6SE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e373c698-e162-47e4-ba8a-f376871d3725.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL6RE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42212cb3-06c9-4e22-b03e-c0f01117a5f6

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH2 | c.8224G>A p.E2742K | Missense Mutation (SNP) | VAF 45/460 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as COSV66719622; called by muse, mutect2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 12/444 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- MX1 | c.1756C>G p.Q586E | Missense Mutation (SNP) | VAF 25/319 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2
